Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABV6, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABV6-TTP1-A (Primary Tumor).

[page 1 of 9]
NOTES: SURGICAL REPORT

Case Type
S

First Name
Middle Name
Last Name
MRN

Billing#

DOB

Order Date +0

Procedure Date +0

Sign Out Date +0

Pathologist ID

Clinic ID

Admitting Doctor

Requesting Doctor

Spec. ID

Received date +0

Source

SURGICAL SPECIMEN, IMPORTED POWERPATH DATA

Body Site

Modifier: Sigmoid Polyp

Spec. ID: B

Received date +0

Source

SURGICAL SPECIMEN, IMPORTED POWERPATH DATA

Body Site

Modifier: Cecal Polyp

Spec. ID: C

Received date +0

Source

SURGICAL SPECIMEN, IMPORTED POWERPATH DATA

Body Site

Modifier: Transverse Polyp

Spec. ID: D

Received date +0

Source

SURGICAL SPECIMEN, IMPORTED POWERPATH DATA

Body Site

Modifier: Rectal Polyp

Spec. ID: E

Received date +0

Source

SURGICAL SPECIMEN, IMPORTED POWERPATH DATA

Body Site

Modifier: Esophagus, Biopsy

[page 2 of 9]
Final Diagnosis:

Specimens: A Sigmoid Polyp

B Cecal Polyp

C Transverse Polyp

D Rectal Polyp

E Esophagus, Biopsy

Macroscopic: A - E. The tissue measures less than 1 cm each.

Microscopic: A. Sections of the colon show featheredge development on the surface.

B. Sections of the colon show featheredge development on the surface. Sections of the colon show a decreased number of goblet cells within the glands and stratification of the nuclei.

C. Sections of the colon show featheredge development on the surface.

D. Sections of the colon show featheredge development on the surface. Sections of the colon show a decreased number of goblet cells within the glands and stratification of the nuclei.

E. Section shows neoplastic cells which have a increase in the nuclear to cytoplasmic ratio. These neoplastic cells are embedded in an ulcerated debris background. In focal areas, there are poorly differentiated gland formation.

Diagnosis: A. HYPERPLASTIC POLYP.

B. MIXED ADENOMATOUS AND HYPERPLASTIC POLYP.

C. HYPERPLASTIC POLYP.

D. MIXED ADENOMATOUS AND HYPERPLASTIC POLYP.

E. POORLY DIFFERENTIATED ADENOCARCINOMA.

Verifying Pathologist:

Date Verified: +1

(electronic signature)

Transcriptionist Initials:

[page 3 of 9]
Contact Information

Procedures signed by

Author: [REDACTED] Service: (none) Author Type: Physician
Filed: [REDACTED] -2 Note Time: [REDACTED] Status: Signed
Editor: [REDACTED] Physician) -2

Procedure Orders:

1. RAD CT [REDACTED] ordered by [REDACTED] -2

RADIOLOGY REPORT - CT

CT SCAN OF THE CHEST [REDACTED] +2

INDICATION: "Lung cancer".

TECHNIQUE: Volume-zoom spiral scans were done from the thoracic inlet through the costophrenic sulci reconstructing axially at 8-mm increments with IV contrast only. Nonionic contrast utilized (100 cc Omnipaque 300).

FINDINGS: Scans viewed at lung settings show both lungs are clear. No primary parenchymal lesions are seen. Scans through the mediastinum do not show any abnormal adenopathy. Normal vascular enhancement is seen. Of note on scans below the diaphragm are diffuse abnormalities in the liver, most likely metastatic in origin.

SUMMARY:

1. The chest CT is essentially normal.
2. Innumerable hepatic lesions, most likely metastatic.

Contact Information

Procedures signed by

Author: [REDACTED] Service: (none) Author Type: Physician
Filed: [REDACTED] -2 Note Time: [REDACTED] Status: Signed
Editor: [REDACTED] Physician) -2

Procedure Orders:

1. RAD GENERAL [REDACTED] ordered [REDACTED] -2

[page 4 of 9]
RADIOLOGY REPORT - GENERAL RADIOLOGY

PA AND LATERAL CHEST -2

INDICATION: Abdomen pain.

FINDINGS: Heart and lungs are negative. No acute or chronic cardiopulmonary problems are seen.

SUMMARY: Negative chest.

Contact Information

Provider

Department

Center

Procedures signed by

Author

Service: (none)

Author Type: Physician

Filed

Note Time:

Status: Signed

Editor

Physician)

-2

Procedure Orders:

1. RAD CT ordered by

-2

RADIOLOGY REPORT - CT

CT SCAN OF THE ABDOMEN AND PELVIS -2

INDICATION: "Rule out appy".

TECHNIQUE: Volume-zoom spiral scans were done from the left atrium through the pelvis reconstructing axially at 8-mm increments with IV and oral contrast. Nonionic contrast utilized (100 cc Omnipaque 300). Biphasic scans through the upper abdominal viscera were performed.

FINDINGS: Examination is abnormal. Scans through the liver show multiple low-density areas in both right and left hepatic lobes. These should be metastatic. Site of origin of these presumed metastases is not apparent. The spleen, pancreas, kidneys and adrenals are normal. The stomach is somewhat thick-walled, but there is no

[page 5 of 9]
[REDACTED]

contrast present in the stomach and it is therefore decompressed and the stomach finding is an indeterminate finding of questionable significance. Oral contrast given has traversed small bowel and much of this has extended into the colon. I don't see any obvious colon masses, although certainly the possibility of colon neoplasm would need to be of consideration in this patient. There is no evidence of ascites or inflammatory mass. Moderate stool is seen throughout the colon. Limited scans through the lung bases are clear.

SUMMARY: Extensive abnormality throughout the liver, most likely metastatic in origin. The site of primary disease is not apparent, although there is some thickening of the stomach which is diffuse, but nonspecific. No acute inflammatory changes are seen.

COMMENT: Findings on this examination were discussed with Doctor [REDACTED]

[REDACTED]

[REDACTED]

[page 6 of 9]
+196 [REDACTED] Imaging Report: CT CHEST W/ CONTRAST

Provider: [REDACTED]

Location of Care: [REDACTED]

This document contains external references

CT CHEST W/ CONTRAST

ORDERING PROVIDER: [REDACTED]

INDICATION: ESOPHAGEAL CANCER

CT SCAN OF THE CHEST WITH CONTRAST

INDICATION: Esophageal carcinoma, follow-up.

TECHNIQUE: Oral contrast given. Multidetector spiral imaging done through chest, abdomen and pelvis with IV contrast.

FINDINGS: Comparison made with the previous examination of [REDACTED] +123 shows no axillary or mediastinal adenopathy. Parenchymal lung windows show no evidence of metastatic foci. There is a small nodular density noted in the anterior right middle lobe which was present on the prior examination and is essentially unchanged in appearance on today's exam. No new abnormalities are seen. No pleural effusion noted.

IMPRESSION: Stable CT of the chest with no evidence of metastatic disease.

CT SCAN OF THE ABDOMEN WITH CONTRAST

INDICATION: Esophageal carcinoma, follow-up.

TECHNIQUE: Oral contrast given. Multidetector spiral imaging done through chest, abdomen and pelvis with IV contrast.

FINDINGS: Imaging from the diaphragm to the iliac crest shows multiple persistent hypodensities throughout the liver which are now less conspicuous and slightly smaller in size than noted on the previous study. Spleen is unchanged in size. Pancreas shows no focal mass or evidence of obstruction. Adrenal glands and kidneys show no appreciable change from the prior study. Both kidneys are well visualized with no mass lesion or evidence of obstruction. No definite mesenteric adenopathy is seen. Remainder of the abdomen shows no additional abnormalities.

IMPRESSION: Decrease in size and conspicuity of the multiple lesions within the liver previously described. This is considerable improvement from a prior study.

CT SCAN OF THE PELVIS WITH CONTRAST

INDICATION: Esophageal carcinoma, follow-up.

[page 7 of 9]
TECHNIQUE: Oral contrast given. Multidetector spiral imaging done through chest, abdomen and pelvis with IV contrast.

FINDINGS: Imaging from the iliac crest to the pelvic floor shows no evidence of mass or free fluid. Lymph nodes noted in the deep pelvis are well below the 1 cm size and are considered normal by size criteria. Mild enlargement of the prostate gland is noted.

IMPRESSION: No evidence of metastatic disease to the pelvis.

CC: [REDACTED]

External Attachment:

Type: Image
Comment: PACS IMAGE

[REDACTED]

[page 8 of 9]
+2485

[REDACTED] Imaging Report: CT ABDOMEN PELVIS WITH CONTRAST

Provider: [REDACTED]

Location [REDACTED]

CT ABDOMEN PELVIS WITH CONTRAST

ORDERING PROVIDER: [REDACTED]

INDICATION: ,Malignant neoplasm of lower third of esophagus,Secondary malignant neoplasm of liver

CT CHEST, ABDOMEN AND PELVIS

INDICATION: History of esophageal cancer with metastatic disease to the liver. +2074

COMPARISON: Study dated [REDACTED] and dating back to [REDACTED] +53

TECHNIQUE: CT of the chest, abdomen and pelvis with IV and oral contrast. 118 mL of Omni-350 was administered intravenously for postcontrast imaging.

CT CHEST

FINDINGS: Stable 2 to 3-mm calcified granuloma identified in the right lung apex along the medial pleura. There is stable mild nodularity of the right major fissure. There is a small, 4 to 5-mm ground glass nodule identified in the right middle lobe, which was present on the prior study dated [REDACTED] and may have been present on the prior studies dated [REDACTED] and [REDACTED]. Small calcified granuloma identified in the right lung base along the medial pleura. There is minimal dependent atelectasis seen in the bilateral lungs. Overall, the appearance of the lungs is stable; with no new lesion or pleural effusion identified. No supraclavicular lymphadenopathy. No axillary lymphadenopathy. There are small, nonenlarged, subcentimeter short axial peribronchial lymph nodes. The esophagus is decompressed, which limits this evaluation. No obvious soft tissue abnormality identified associated with the esophagus. There is atherosclerotic calcification of the coronary arteries as well as the mitral and aortic valves. +2074 +1554

CT ABDOMEN

FINDINGS: The liver is grossly normal in appearance. No focal liver lesion appreciated. The gallbladder, pancreas, spleen, bilateral adrenal glands and right kidney are grossly normal in appearance. There are two exophytic low attenuation lesions seen on the inferior aspect of the left kidney which are grossly similar in appearance when compared to the prior study dated [REDACTED] and are likely cysts. No hydronephrosis. The bilateral ureters are grossly normal in appearance. There is no abdominal lymphadenopathy. There is a moderate amount of stool seen throughout the colon. The appendix is normal. +1554

CT PELVIS

FINDINGS: There is no free fluid within the pelvis. There is mild atherosclerotic calcification involving the abdominal aorta and the iliac vessels. The prostate is mildly enlarged. The urinary bladder is grossly normal in appearance. No pelvic lymphadenopathy.

+1676

[page 9 of 9]
[REDACTED]

There are a few scattered diverticula in the descending colon, without evidence of diverticulitis. No aggressive lytic or blastic lesion is seen throughout the osseous structures. There are mild degenerative changes seen in the lower thoracic spine and the lumbar spine.

IMPRESSION:

1. Stable 4 to 5-mm ground glass nodule identified in the right middle lung lobe. This was present but slightly less apparent on the prior study dated [REDACTED] +1554
2. Atherosclerotic calcification of the mitral and aortic valves.
3. Stable left renal cysts.
4. Otherwise, no evidence of recurrent or metastatic disease.

CC:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 32e41344-6443-4961-ae63-2c462613525b (ER0211 ER-ABV6 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).